Gene-level copy-number profile of tumor specimen TCGA-ZF-AA51-01A from TCGA case TCGA-ZF-AA51, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 69.8 years (25,484 days).
Specimen TCGA-ZF-AA51-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.525935c9-0548-4cbd-827f-1536f0e92e9c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA51-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72804d99-45a7-4cef-a325-1b7a7d4a3a4f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 274; copy number 2: 20,167; copy number 3: 14,007; copy number 4: 14,812; copy number 5: 3,768; copy number 6: 4,423; copy number 7: 1,357; copy number 8: 525; copy number 9: 189; copy number 10: 126; copy number 11: 41; copy number 12: 6; copy number 13: 63; copy number 15: 11; copy number 18: 14; copy number 20: 10; copy number 27: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA51-01A-21D-A390-01): tumor purity 0.5, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr16:78,055,824–78,056,927, 1 gene: AC079414.2.
- chr16:78,123,243–78,553,296, 9 genes: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,538 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–24,364,482, 785 genes, copy number 6 (broad region; genes not listed).
- chr1:75,122,518–161,100,346, 1,644 genes, copy number 5–6 (broad region; genes not listed).
- chr1:163,422,405–163,509,595, 3 genes, copy number 7: AL603841.1, RNA5SP62, RNA5SP63.
- chr1:200,333,193–201,469,237, 29 genes, copy number 8 (within-gene range 4–8): AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2.
- chr2:38,814–32,039,805, 544 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:32,628,032–32,821,051, 1 gene, copy number 7 (within-gene range 4–7): TTC27.
- chr2:32,825,359–88,186,636, 948 genes, copy number 5–8 (broad region; genes not listed).
- chr2:102,967,408–103,623,830, 8 genes, copy number 6: LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1.
- chr2:111,006,015–118,222,250, 134 genes, copy number 5–20 (broad region; genes not listed).
- chr2:123,762,171–126,702,942, 22 genes, copy number 5–7: PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3, YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P.
- chr2:131,647,990–133,596,399, 44 genes, copy number 9–12 (within-gene range 3–12): C2orf27A, AC093838.2, NBEAP2, TOMM40P4, CDRT15P4, CDRT15P3, AC103564.3, AC103564.1, AC103564.2, AJ239322.2, AJ239322.1, LINC01945, AC093787.2, AC093787.1, AC098826.3, AC098826.1, AC098826.2, ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93.
- chr2:134,718,188–135,531,218, 11 genes, copy number 8 (within-gene range 4–8): AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3.
- chr3:11,745–59,754,808, 1,098 genes, copy number 5–8 (broad region; genes not listed).
- chr3:61,561,569–90,261,708, 277 genes, copy number 5–7 (broad region; genes not listed).
- chr3:169,709,295–198,222,513, 584 genes, copy number 5 (broad region; genes not listed).
- chr4:1,574,062–3,590,711, 56 genes, copy number 5–7: AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1, RGS12, AL645949.1, AL645949.2, HGFAC, AL590235.2, DOK7, LRPAP1, AL590235.1, LINC00955.
- chr4:4,174,319–4,419,058, 7 genes, copy number 7 (within-gene range 2–7): OR7E43P, OTOP1, TMEM128, LYAR, ZBTB49, AC105415.1, NSG1.
- chr4:11,914,667–12,312,690, 3 genes, copy number 8: AC108037.1, LINC02270, RNU6-578P.
- chr4:13,333,414–14,888,169, 22 genes, copy number 5–7: HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63.
- chr5:602,620–29,516,504, 422 genes, copy number 5–9 (broad region; genes not listed).
- chr5:29,795,938–45,895,970, 264 genes, copy number 5–7 (broad region; genes not listed).
- chr6:106,969,831–107,958,208, 12 genes, copy number 20–27 (within-gene range 2–27): CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63.
- chr7:53,655,508–57,485,895, 141 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr8:35,862,123–81,284,777, 721 genes, copy number 5–11 (broad region; genes not listed).
- chr8:84,182,787–92,352,148, 109 genes, copy number 6 (broad region; genes not listed).
- chr10:44,712–14,774,897, 258 genes, copy number 5 (broad region; genes not listed).
- chr10:15,513,954–38,783,108, 396 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:49,818,279–52,772,784, 45 genes, copy number 5–7 (within-gene range 2–7): PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2.
- chr11:34,621,093–35,918,739, 23 genes, copy number 13: EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1.
- chr11:35,967,010–35,989,007, 2 genes, copy number 11–13 (within-gene range 3–13): AL136146.1, AL136146.2.
- chr11:98,565,074–100,358,885, 5 genes, copy number 6 (within-gene range 2–6): AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53.
- chr12:38,078,529–40,369,285, 34 genes, copy number 5: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1.
- chr12:40,395,853–40,443,847, 1 gene, copy number 5 (within-gene range 2–5): AC107023.1.
- chr12:110,910,819–112,509,918, 44 genes, copy number 7: MYL2, LINC01405, AC002351.1, CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11.
- chr19:867,630–1,174,268, 20 genes, copy number 10: MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2.
- chr19:9,538,693–12,551,474, 180 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).
- chr19:38,433,691–58,605,223, 1,316 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:87,250–916,334, 26 genes, copy number 6 (within-gene range 4–6): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4.
- chr20:32,762,385–35,412,031, 92 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:33,229,901–42,496,246, 205 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
